Somatic mutation profile of tumor specimen TCGA-E1-A7YJ-01A (aliquot TCGA-E1-A7YJ-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YJ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 55.2 years (20,180 days).
Specimen TCGA-E1-A7YJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7517a402-2ec4-41b2-b340-de22a06170e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YJ-10A (Blood Derived Normal), aliquot TCGA-E1-A7YJ-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e2cfbe4-15e8-4729-acae-a016f3372b4e

The open-access MAF lists 47 somatic variants for this specimen: 30 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 16, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 242/3630 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV51767495, COSV51850592; called by muse, mutect2
- AGBL1 | c.2436G>A p.W812* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs998063317, COSV101222454; called by muse, mutect2
- BAG3 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV64841983; called by muse, mutect2, varscan2
- CCAR1 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 40/72 reads (56%) | catalogued as rs1295638429, COSV99770799; called by muse, mutect2, varscan2
- CCDC39 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.795); catalogued as rs540660862, COSV56479847, COSV56482766, COSV56484585; called by muse, mutect2, varscan2
- CCDC8 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100281949; called by muse, mutect2, varscan2
- CRB1 | c.802A>C p.S268R | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100958551; called by muse, mutect2, varscan2
- CRHR2 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100529705; called by muse, mutect2
- CUX2 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs774611463; called by muse, varscan2
- CWC25 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.247); catalogued as rs370528083; called by muse, mutect2, varscan2
- DHX29 | c.889A>G p.I297V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99287116; called by muse, mutect2, varscan2
- EPHB2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65860322; called by muse, mutect2, varscan2
- EPN1 | c.175A>G p.M59V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99321723; called by muse, mutect2, varscan2
- FAM167B | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747746477, COSV61107373; called by muse, mutect2, varscan2
- FAP | c.2025G>C p.E675D | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99501975; called by muse, mutect2, varscan2
- HMCN1 | c.4940C>T p.T1647M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs775412545, COSV54909021; called by muse, mutect2, varscan2
- KRT34 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV101222587; called by muse, mutect2, varscan2
- MATN4 | c.1408C>T p.R470W (on ENST00000372754; = p.R429W on NM_003833.4) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | PolyPhen probably damaging (0.985); catalogued as rs372468063; called by muse, mutect2, varscan2
- NDRG4 | c.1006G>A p.E336K (on ENST00000570248 / NM_001378344.1; = p.E355K on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99261843; called by muse, mutect2, varscan2
- OR2T3 | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100613156; called by muse, mutect2, varscan2
- PLEKHG4 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs775644209, COSV58574670; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- PTPN13 | c.5837A>T p.E1946V (on ENST00000411767 / NM_080683.3; = p.E1927V on NM_006264.3) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100364390; called by muse, mutect2, varscan2
- RIMBP2 | c.751T>A p.F251I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV99898834; called by muse, mutect2
- SERPINB2 | c.168+2T>A p.X56_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100208280; called by muse, mutect2, varscan2
- YBX2 | c.1081A>C p.T361P | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.369); catalogued as COSV99142673; called by muse, mutect2
- GCC2 | c.1004_1007del p.K335Tfs*2 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- TAF2 | c.1832_1834del p.E611del | In Frame Del (DEL) | VAF 24/85 reads (28%) | called by pindel, varscan2
- TRIM32 | c.1162_1174delinsACC p.A388Tfs*14 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | called by pindel, varscan2*
- WDR20 | c.1655_1656del p.E552Gfs*11 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | called by mutect2, pindel, varscan2
- BPHL | c.675C>T p.C225= | Silent (SNP) | VAF 57/158 reads (36%) | catalogued as rs748796244, COSV100984448, COSV66744618; called by muse, mutect2, varscan2
- C8A | c.504C>T p.Y168= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs777567965, COSV63483634; called by muse, mutect2, varscan2
- FBXO31 | c.507C>T p.I169= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100291329; called by muse, mutect2, varscan2
- FGA | c.2409T>C p.Y803= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV100120199; called by muse, mutect2, varscan2
- GPATCH2L | c.345C>T p.D115= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV99833480; called by muse, mutect2, varscan2
- KCNH6 | c.1179C>T p.Y393= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV100120889; called by muse, mutect2, varscan2
- KRT5 | c.1251C>T p.A417= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs553666316, COSV99357887; called by muse, mutect2, varscan2
- ODF3L1 | c.309G>A p.P103= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs758383665, COSV100150735; called by muse, varscan2
- OTOF | c.2517G>A p.A839= (on ENST00000272371 / NM_194248.3; = p.A92= on NM_004802.4) | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs773993511, COSV55516572; called by muse, mutect2, varscan2
- PCDHGA1 | c.2190C>T p.G730= | Silent (SNP) | VAF 44/120 reads (37%) | catalogued as COSV65294725; called by muse, mutect2, varscan2
- PRPF19 | c.1458C>T p.H486= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs751325779, COSV57127199; called by muse, mutect2, varscan2
- RAB36 | c.948G>T p.G316= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV54074218, COSV99572140; called by muse, varscan2
- SFRP2 | c.762C>T p.N254= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs995413065, COSV56837651; called by muse, mutect2, varscan2
- SLC17A7 | c.1326C>T p.N442= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs971797832, COSV55548445; called by muse, mutect2, varscan2
- SULT1E1 | c.756G>A p.S252= | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as rs376968582; called by muse, mutect2, varscan2
- TTN | c.36645C>T p.N12215= (on ENST00000591111; = p.N4791= on NM_003319.4) | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs559906667, COSV100601664; ClinVar: likely benign; called by muse, mutect2, varscan2
- WNK1 | c.2140-3112A>G | Intron (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100266724; called by muse, mutect2, varscan2
